Gene-level copy-number profile of tumor specimen C3N-00573-01 from CPTAC case C3N-00573, project CPTAC-3 (Kidney — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Renal cell carcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage II; Tumor grade: G2; Age at diagnosis: 61.3 years (22,407 days).
Specimen C3N-00573-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Kidney; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file fc650c2f-993c-4223-bb61-0b01f06abc07.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3N-00573-71 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,710 have no estimate.
https://portal.gdc.cancer.gov/files/8ac769a4-1714-41ef-889f-4afdefba4ff9

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 1; copy number 2: 6,356; copy number 3: 1,049; copy number 4: 45,851; copy number 5: 152; copy number 6: 5,485; copy number 7: 11; copy number 9: 1; copy number 12: 3; copy number 13: 2; copy number 17: 1; copy number 25: 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 8 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:87,654,890–87,655,243, 1 gene, copy number 17: RPS14P5.
- chr3:130,048,143–130,055,920, 1 gene, copy number 9: AC083906.4.
- chr6:170,651,012–170,696,950, 2 genes, copy number 13: WBP1LP8, AL731661.1.
- chr15:101,961,603–101,979,093, 3 genes, copy number 12: WASH3P, MIR6859-3, DDX11L9.
- chr16:90,173,217–90,222,851, 1 gene, copy number 25 (within-gene range 6–25): LINC02193.

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
